Somatic mutation profile of tumor specimen C3L-04731-05 (aliquot CPT0258360006) from CPTAC case C3L-04731, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 65.1 years (23,774 days).
Specimen C3L-04731-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) da94c85a-71e8-4305-a4a5-adeee7ea7ec3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-04731-31 (Blood Derived Normal), aliquot CPT0258420002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2c6e762a-7b4c-4c9e-ae59-4542e1e288c1

The open-access MAF lists 103 somatic variants for this specimen: 69 protein-altering or splice-affecting, 27 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 27, Nonsense Mutation 6, Frame Shift Del 4, RNA 3, Translation Start Site 1, Frame Shift Ins 1, 3'UTR 1, Intron 1, Splice Site 1, 5'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.330G>A p.W110* | Nonsense Mutation (SNP) | VAF 253/506 reads (50%) | hotspot (GDC flag); catalogued as rs121913389, CM060208, COSV58682827, COSV58708986; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADCY9 | c.3523G>A p.G1175R | Missense Mutation (SNP) | VAF 101/310 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1158584676; called by muse, mutect2, varscan2
- ADGRV1 | c.253G>T p.A85S | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.619); catalogued as COSV67996722; called by muse, mutect2
- AFF3 | c.2476G>T p.E826* | Nonsense Mutation (SNP) | VAF 40/120 reads (33%) | catalogued as COSV57872410; called by muse, mutect2, varscan2
- BTBD8 | c.3175C>T p.H1059Y (on ENST00000636805 / NM_001376131.1; = p.H546Y on NM_015237.4) | Missense Mutation (SNP) | VAF 61/169 reads (36%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.836); catalogued as rs545083953; called by muse, mutect2, varscan2
- CREBBP | c.4649A>G p.E1550G | Missense Mutation (SNP) | VAF 149/455 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52121524; called by muse, mutect2, varscan2
- DNAH6 | c.10139G>A p.R3380H | Missense Mutation (SNP) | VAF 72/211 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.325); catalogued as rs559229507, COSV99405815; called by muse, mutect2, varscan2
- EN1 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 15/310 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.151); catalogued as rs1369989896; called by muse, mutect2
- EPHA1 | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 133/570 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV51970732; called by muse, mutect2, varscan2
- GIGYF2 | c.778C>T p.R260* | Nonsense Mutation (SNP) | VAF 99/265 reads (37%) | catalogued as COSV65247085, COSV65251490; called by muse, mutect2, varscan2
- HTR5A | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 105/449 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs751304245; called by muse, mutect2, varscan2
- INTS14 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 105/466 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.838); catalogued as rs761348752, COSV57527733; called by muse, mutect2, varscan2
- KCTD11 | c.524C>T p.A175V (on ENST00000333751 / NM_001363642.1; = p.A136V on NM_001002914.2) | Missense Mutation (SNP) | VAF 123/457 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as rs769204157; called by muse, mutect2, varscan2
- KLRC4 | c.343C>T p.R115C | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.02); catalogued as rs752700630, COSV58671668; called by muse, mutect2, varscan2
- LDHAL6B | c.362C>T p.T121M | Missense Mutation (SNP) | VAF 128/325 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.017); catalogued as COSV55684284; called by muse, mutect2, varscan2
- MUC4 | c.5374C>T p.R1792C | Missense Mutation (SNP) | VAF 137/1352 reads (10%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.685); catalogued as rs552010357; called by muse, varscan2
- NCKIPSD | c.1175G>A p.R392Q | Missense Mutation (SNP) | VAF 65/213 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.258); catalogued as rs753041351; called by muse, mutect2, varscan2
- NF1 | c.1186-1G>A p.X396_splice | Splice Site (SNP) | VAF 67/141 reads (48%) | catalogued as COSV62200893, COSV62215356, COSV62223155; called by muse, mutect2, varscan2
- NPHP3 | c.2251del p.V751Ffs*17 | Frame Shift Del (DEL) | VAF 41/179 reads (23%) | catalogued as COSV100446730; called by mutect2, pindel, varscan2
- PIK3R1 | c.1709T>C p.L570P (on ENST00000521381 / NM_181523.3; = p.L300P on NM_181504.4) | Missense Mutation (SNP) | VAF 6/127 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57123228, COSV57133965; called by muse, mutect2
- PLCG2 | c.1960G>A p.G654R | Missense Mutation (SNP) | VAF 88/272 reads (32%) | SIFT tolerated (0.5); PolyPhen benign (0.24); catalogued as rs1295648437; called by muse, mutect2, varscan2
- PROP1 | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 20/218 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs745650009, COSV57644616; called by muse, mutect2
- PSG9 | c.829G>A p.G277S | Missense Mutation (SNP) | VAF 42/301 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs1311205237, COSV52486471, COSV99392067; called by muse, mutect2, varscan2
- PSMB11 | c.559G>A p.V187M | Missense Mutation (SNP) | VAF 53/182 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs200046969; called by muse, mutect2, varscan2
- PTEN | c.476G>C p.R159T | Missense Mutation (SNP) | VAF 78/143 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM110131, COSV64288635, COSV64288792; called by muse, mutect2, varscan2
- RYR1 | c.11939C>T p.A3980V | Missense Mutation (SNP) | VAF 40/675 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV62088299; called by muse, mutect2
- SEMA3E | c.374A>G p.Y125C | Missense Mutation (SNP) | VAF 146/561 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1224527955; called by muse, mutect2, varscan2
- SHTN1 | c.1634G>A p.R545H | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs749169785; called by muse, mutect2, varscan2
- SIRPG | c.448G>A p.V150M | Missense Mutation (SNP) | VAF 34/163 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.03); catalogued as rs373555109; called by muse, mutect2
- SLC2A4RG | c.434C>T p.P145L | Missense Mutation (SNP) | VAF 88/234 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as rs752686126, COSV99828836; called by muse, mutect2, varscan2
- SLCO4C1 | c.515C>T p.P172L | Missense Mutation (SNP) | VAF 13/305 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as rs1312466031, COSV60517698; called by muse, mutect2
- STYK1 | c.1097G>A p.R366H | Missense Mutation (SNP) | VAF 97/264 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs189204525, COSV50013041; called by muse, mutect2, varscan2
- TAFA1 | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 51/153 reads (33%) | SIFT tolerated (0.77); PolyPhen benign (0.338); catalogued as rs754121777, COSV72037425; called by muse, mutect2, varscan2
- TRIM40 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 74/167 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs1410035990; called by muse, mutect2, varscan2
- TTN | c.69302G>A p.R23101H (on ENST00000591111; = p.R15677H on NM_003319.4) | Missense Mutation (SNP) | VAF 21/63 reads (33%) | PolyPhen benign (0.013); catalogued as rs761823581, COSV60105668; called by muse, mutect2, varscan2
- ACRV1 | c.133T>C p.S45P | Missense Mutation (SNP) | VAF 39/143 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ACTBL2 | c.862G>A p.V288M | Missense Mutation (SNP) | VAF 109/279 reads (39%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- AK9 | c.2167del p.E723Nfs*3 | Frame Shift Del (DEL) | VAF 38/196 reads (19%) | called by mutect2, pindel, varscan2
- CD164 | c.437A>G p.N146S | Missense Mutation (SNP) | VAF 67/218 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- CFAP69 | c.852del p.E284Dfs*6 | Frame Shift Del (DEL) | VAF 15/66 reads (23%) | called by mutect2, pindel, varscan2
- CWC22 | c.902G>C p.G301A | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ENC1 | c.671A>T p.K224M | Missense Mutation (SNP) | VAF 77/240 reads (32%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- EPC2 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 72/234 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- FAM122B | c.501A>C p.K167N (on ENST00000370790 / NM_001166599.3; = p.K168N on NM_145284.5) | Missense Mutation (SNP) | VAF 57/72 reads (79%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FARP2 | c.1667T>C p.V556A | Missense Mutation (SNP) | VAF 64/180 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GYS2 | c.1757G>C p.R586T | Missense Mutation (SNP) | VAF 59/253 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HR | c.2525C>T p.P842L | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- IRS1 | c.3224T>C p.V1075A | Missense Mutation (SNP) | VAF 57/161 reads (35%) | SIFT tolerated (0.59); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KCNC2 | c.904G>T p.V302F | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- NAA16 | c.1600A>G p.T534A | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NBEA | c.1027C>T p.R343W | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- P2RY8 | c.745T>A p.C249S | Missense Mutation (SNP) | VAF 22/320 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCDHB13 | c.1392C>G p.N464K | Missense Mutation (SNP) | VAF 184/650 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PDIA3 | c.447del p.S150Vfs*7 | Frame Shift Del (DEL) | VAF 29/94 reads (31%) | called by mutect2, pindel, varscan2
- PPP6R1 | c.520G>T p.E174* | Nonsense Mutation (SNP) | VAF 89/226 reads (39%) | called by muse, mutect2, varscan2
- QSER1 | c.1201G>A p.V401I (on ENST00000399302; = p.V530I on NM_001076786.3) | Missense Mutation (SNP) | VAF 45/113 reads (40%) | SIFT tolerated (0.64); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- RBM10 | c.1427C>G p.T476S | Missense Mutation (SNP) | VAF 51/65 reads (78%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- RUSC2 | c.2233G>C p.A745P | Missense Mutation (SNP) | VAF 40/401 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.087); called by muse, mutect2
- SATB1 | c.2020G>T p.A674S | Missense Mutation (SNP) | VAF 98/300 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC16A7 | c.680A>G p.K227R | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT tolerated (0.58); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SLC44A5 | c.2155G>T p.E719* | Nonsense Mutation (SNP) | VAF 48/119 reads (40%) | called by muse, mutect2, varscan2
- SLC4A10 | c.545A>T p.D182V | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SOX10 | c.395C>G p.A132G | Missense Mutation (SNP) | VAF 7/196 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- SOX2 | c.701_702dup p.M235Afs*40 | Frame Shift Ins (INS) | VAF 72/711 reads (10%) | called by mutect2, pindel, varscan2
- TJP2 | c.1885G>T p.E629* | Nonsense Mutation (SNP) | VAF 8/192 reads (4%) | called by muse, mutect2
- USP19 | c.2105G>C p.S702T | Missense Mutation (SNP) | VAF 52/191 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- XAGE2 | c.232A>G p.T78A | Missense Mutation (SNP) | VAF 125/195 reads (64%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- XPNPEP2 | c.1342C>A p.L448M | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- ZNF716 | c.1023A>T p.K341N | Missense Mutation (SNP) | VAF 109/463 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AKR1B10 | c.915T>C p.S305= | Silent (SNP) | VAF 92/378 reads (24%) | called by muse, mutect2, varscan2
- AP3B2 | c.1386G>T p.V462= | Silent (SNP) | VAF 57/183 reads (31%) | called by muse, mutect2, varscan2
- C7 | c.924G>A p.S308= | Silent (SNP) | VAF 36/117 reads (31%) | catalogued as rs772715061, COSV100495960; called by muse, mutect2, varscan2
- DLX6 | c.768C>T p.D256= | Silent (SNP) | VAF 44/727 reads (6%) | catalogued as rs769967866, COSV99142195; called by muse, mutect2
- DNTTIP1 | c.156C>T p.R52= | Silent (SNP) | VAF 6/138 reads (4%) | called by muse, mutect2
- EHBP1 | c.444C>T p.A148= | Silent (SNP) | VAF 7/71 reads (10%) | catalogued as rs375725835; called by muse, mutect2, varscan2
- HEPACAM2 | c.27C>T p.P9= | Silent (SNP) | VAF 65/234 reads (28%) | called by muse, mutect2, varscan2
- KCNH6 | c.2013T>C p.S671= | Silent (SNP) | VAF 16/296 reads (5%) | called by muse, mutect2
- KMT5A | c.246A>G p.K82= | Silent (SNP) | VAF 21/346 reads (6%) | called by muse, mutect2
- LAMA1 | c.6219C>T p.D2073= | Silent (SNP) | VAF 82/292 reads (28%) | catalogued as rs751773541, COSV67531675; called by muse, mutect2, varscan2
- LDLRAD4 | c.525C>T p.S175= | Silent (SNP) | VAF 19/266 reads (7%) | catalogued as rs867383899, COSV63343869; called by muse, mutect2
- LRP2 | c.10803C>T p.C3601= | Silent (SNP) | VAF 90/273 reads (33%) | catalogued as rs370876114; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYO9B | c.1803C>T p.H601= | Silent (SNP) | VAF 47/144 reads (33%) | catalogued as rs758252048; called by muse, mutect2, varscan2
- NLRP2 | c.1419C>T p.L473= | Silent (SNP) | VAF 13/230 reads (6%) | catalogued as rs563587847, COSV54753387; called by muse, mutect2
- PCDHA12 | c.1314G>A p.T438= | Silent (SNP) | VAF 198/580 reads (34%) | catalogued as rs1316558090, COSV56475128, COSV56490111; called by muse, mutect2, varscan2
- PCDHA2 | c.2046G>A p.A682= | Silent (SNP) | VAF 114/309 reads (37%) | called by muse, mutect2, varscan2
- PDZD3 | c.1224C>T p.V408= (on ENST00000531114; = p.V328= on NM_024791.4) | Silent (SNP) | VAF 32/93 reads (34%) | catalogued as rs1270405754; called by muse, mutect2, varscan2
- PTPRC | c.837G>A p.A279= | Silent (SNP) | VAF 39/180 reads (22%) | catalogued as rs137909392; ClinVar: likely benign; called by muse, mutect2, varscan2
- SBK3 | c.918C>T p.D306= | Silent (SNP) | VAF 31/118 reads (26%) | catalogued as rs543963870; called by muse, mutect2, varscan2
- SLC4A2 | c.2457C>G p.V819= | Silent (SNP) | VAF 114/494 reads (23%) | called by muse, mutect2, varscan2
- SVIL | c.3621C>T p.N1207= (on ENST00000355867 / NM_021738.3; = p.N781= on NM_003174.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/185 reads (9%) | catalogued as rs137909858; called by muse, mutect2
- TBX19 | c.681C>T p.D227= | Silent (SNP) | VAF 111/386 reads (29%) | catalogued as rs776410135, COSV63197081; called by muse, mutect2, varscan2
- TBX20 | c.819G>A p.T273= | Silent (SNP) | VAF 65/317 reads (21%) | catalogued as rs776684707, COSV68786569; called by muse, mutect2, varscan2
- TCHH | c.2436G>A p.P812= | Silent (SNP) | VAF 92/273 reads (34%) | catalogued as COSV100914829; called by muse, mutect2, varscan2
- UMOD | c.1029G>A p.S343= | Silent (SNP) | VAF 144/494 reads (29%) | catalogued as rs375846119, COSV56773517, COSV56778852; called by muse, mutect2, varscan2
- USH2A | c.14904C>T p.D4968= | Silent (SNP) | VAF 95/167 reads (57%) | catalogued as rs151165599, COSV56358752; called by muse, mutect2, varscan2
- ZNF780A | c.687C>G p.A229= | Silent (SNP) | VAF 43/162 reads (27%) | catalogued as COSV61814462; called by muse, mutect2, varscan2
- DCHS2 | n.752A>G | RNA (SNP) | VAF 24/79 reads (30%) | catalogued as rs1401957936, COSV59725049; called by muse, mutect2, varscan2
- EFHC1 | c.*2025G>C | 3'UTR (SNP) | VAF 53/288 reads (18%) | called by muse, mutect2, varscan2
- FLT1 | c.1552-2024G>A | Intron (SNP) | VAF 32/117 reads (27%) | called by muse, mutect2, varscan2
- FUNDC2P2 | n.493G>A | RNA (SNP) | VAF 42/397 reads (11%) | called by muse, mutect2, varscan2
- NCF1C | n.882C>T | RNA (SNP) | VAF 8/32 reads (25%) | catalogued as rs1554531130; called by mutect2, varscan2
- PSG9 | c.-15C>A | 5'UTR (SNP) | VAF 46/153 reads (30%) | called by muse, mutect2, varscan2
- RPL37AP1 | chr20:44461997 C>T | 3'Flank (SNP) | VAF 96/318 reads (30%) | catalogued as rs569712213; called by muse, mutect2, varscan2
